Surgical pathology report (de-identified scan), TCGA case TCGA-56-A5DR, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-A5DR-01A (Primary Tumor).

[page 1 of 3]
Patient: [REDACTED]

Printed by [REDACTED]

Page 1 of 3

Description: year old male

Department: [REDACTED]

Encounter Report

Transcription Result

Type
Surgical Pathology

ID
[REDACTED]

Dictation Date/Time

Author
[REDACTED]

Authenticated by [REDACTED]

Document Text

SURGERY CASE #: [REDACTED] FINAL

DATE OF SURGERY:

SURGEON:

[REDACTED] MD

SPECIMEN:

- A. Level 4
- B. Level 11
- C. Level 11
- D. Left upper lobe.
- E. Level 4

ICD-O-3
Carcinoma, Squamous Cell
NOS 887013

Site: (L) Lung, upper lobe
c34.1

9/12/24/12

FROZEN SECTION DIAGNOSIS: B. Carcinoma.
Bronchial surgical margin free of tumor.

OPERATIVE PROCEDURE: Limited left thoracotomy with upper
lobectomy.

PREOPERATIVE DIAGNOSIS: Left lung mass.

POSTOPERATIVE DIAGNOSIS: None given.

*****DIAGNOSIS*****

A-E.

1. Type of specimen:
Left upper lobe lobectomy with lymph node biopsies.
2. Tumor type:
Squamous cell carcinoma.
3. Histologic grade:
Poorly differentiated.
4. Tumor size:
1.8 cm.
5. Surgical margins:
All surgical margins free of tumor.
6. Direct extension of tumor:
Not identified.
7. Lymphatic (small vessel) invasion:
Absent.
8. Venous (large vessel) invasion:
Absent.
9. Lymph nodes:
Total number of lymph nodes examined: 6.

[REDACTED]

[page 2 of 3]
Number of lymph nodes involved: 0 (0/6).

10. TNM STAGING:
pT1a, pN0, pMx

(See previous [REDACTED] and [REDACTED].

88305, 88305, 88305, 88331, 88332, 88309, 88305

MICROSCOPIC EXAMINATION:

- A. Sections are of a benign lymph node with anthracotic pigment. There is no malignancy.
- B. Sections are of a benign lymph node with similar findings as described above. There is no malignancy.
- C. Sections are of a benign lymph node. There is no malignancy.
- D. Multiple sections are examined and sections of the vascular and bronchial surgical margins are free of tumor. There are two benign peribronchial lymph nodes with no malignancy. Sections of the tumor grossly described are composed of sheets of neoplastic cells with somewhat distinct cell borders with a small to moderate amount of cytoplasm and large pleomorphic nuclei with irregularly clumped chromatin pattern and prominent nucleoli and mitotic activity. There is no definite lymphovascular invasion seen. Sections of the grossly uninvolved lung demonstrate no significant fibrosis or significant inflammation.
- E. Sections are of a benign lymph node with no malignancy. [REDACTED]

GROSS:

- A. Received in Formalin labeled with the patient's name, account number, and "L4" is a single slightly anthracotic lymph node measuring 0.9 x 0.5 x 0.3 cm. The specimen is totally submitted in a single cassette. TS-1 [REDACTED]
- B. Received in Formalin labeled with the patient's name, account number, and "L11" is a single slightly anthracotic lymph node measuring 0.7 x 0.6 x 0.3 cm. The specimen is totally submitted in a single cassette. TS-1 [REDACTED]
- C. Received in Formalin labeled with the patient's name, account number, and "more L11" is a single anthracotic lymph node measuring 1.5 x 0.8 x 0.3 cm. The specimen is totally submitted in a single cassette. TS-1 [REDACTED]
- D. Received labeled "left upper lobe" is a 20 x 8 x 6 cm in maximum dimensions lobectomy specimen. The bronchial margin is submitted for frozen section and frozen section diagnosis in block #1. The specimen is serially sectioned and there is a central firm tumor with a white-tan cut surface measuring up to 1.8 cm maximally. Representative section of the tumor is submitted for frozen section and frozen section diagnosis in block #2. Representative section is also submitted for Genomics Project. The remainder of the lung is soft and spongy and mildly anthracotic. Sections are then submitted for permanent as follows: Cassette #3 - Vascular margins and lymph nodes. #4 and #5 - Additional sections of tumor. #6 - Grossly uninvolved lung. [REDACTED]
- E. Received in Formalin labeled with the patient's name, account number, and "L4" is a single anthracotic lymph node measuring 1.7 x 1 x 0.3 cm. The specimen is totally submitted in a single cassette. TS-1 [REDACTED]

[page 3 of 3]
Electronically Signed by [REDACTED]

[REDACTED] MD

Dictated: Job# [REDACTED]
Transcribed: Doc# [REDACTED]

CC: [REDACTED] MD
[REDACTED] MD
[REDACTED] MD

Transcription History

Service
Date/Time
Filed
Date/Time

[REDACTED]	Treatment Team Report All Treatment Team for Encounter
------------	---

[REDACTED]

H/PAA Discrepancy		✓

[REDACTED]

Source: NCI Genomic Data Commons file ccc0ccbf-d773-4a9e-9ac5-4d05c305e941 (TCGA-56-A5DR.569C859A-67CF-4501-B0E3-66715FD193FA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).